Somatic mutation profile of tumor specimen RC-B6E6-TTP1-A (aliquot RC-B6E6-TTP1-A-1-1-D-A93N-47) from RC case RC-B6E6, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 56.8 years (20,761 days).
Specimen RC-B6E6-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21f9e540-f6f3-45e2-8769-a3bc0c27fc21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6E6-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot RC-B6E6-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f93bd304-ce37-4864-8d0c-d76bf3098a14

The open-access MAF lists 49 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 13/178 reads (7%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2
- ABCC9 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs781206225, COSV53987558; ClinVar: uncertain significance; called by muse, mutect2
- ARHGEF28 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.025); catalogued as rs904015530, COSV55246902; called by muse, mutect2
- FSCN2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs782187587; called by muse, mutect2
- KLF3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs377705302; called by muse, mutect2, varscan2
- LIN7A | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1318199370, COSV54019496; called by muse, mutect2, varscan2
- LLGL2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as rs1422767452; called by muse, mutect2
- MARCO | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV59056060; called by muse, mutect2
- MPDZ | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV100064221; called by muse, mutect2, varscan2
- NLGN1 | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs200936288; called by muse, mutect2, varscan2
- OLR1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs267603272; called by muse, mutect2
- PCDHGA2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs886859909; called by muse, varscan2
- PKD1 | c.8687C>T p.S2896F | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs142116197, COSV51911098; called by mutect2, varscan2
- PKNOX2 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1017663986, COSV53541824; called by muse, mutect2
- PTPRF | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330678973; called by muse, mutect2, varscan2
- RNFT1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | catalogued as rs780311442; called by muse, mutect2, varscan2
- TLL1 | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV50322562; called by muse, mutect2, varscan2
- TNC | c.3982G>A p.G1328S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1024520572; called by muse, mutect2
- TRPM2 | c.4333G>A p.V1445I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs751737739, COSV55965716; called by muse, mutect2, varscan2
- VAV1 | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV58378585, COSV58382482; called by muse, mutect2, varscan2
- ZC3H12A | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV66104505; called by muse, mutect2, varscan2
- ZMYM5 | c.1702C>T p.L568F | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV61988784; called by muse, mutect2, varscan2
- ZP4 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs772372321, COSV100850773, COSV63912858; called by muse, mutect2
- AIF1L | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); called by muse, mutect2
- IPO13 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- KCNG2 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | called by muse, varscan2
- MYCT1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- PCDH11X | c.2754G>T p.K918N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PLXNA3 | c.5126C>T p.P1709L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- POM121L2 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ROS1 | c.4360C>T p.P1454S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2
- RYR2 | c.6787G>A p.E2263K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SOX13 | c.969del p.S324Afs*82 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | called by mutect2, pindel, varscan2
- SPEN | c.4261A>T p.R1421* | Nonsense Mutation (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- SPEN | c.6121del p.Q2041Rfs*23 | Frame Shift Del (DEL) | VAF 13/137 reads (9%) | called by mutect2, varscan2
- STC1 | c.569T>G p.M190R | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- SYT9 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAJ52 | chr14:22486227 GCTAAT>CCACCG | Missense Mutation (ONP) | VAF 6/42 reads (14%) | called by mutect2*, pindel
- EML5 | c.4008T>C p.P1336= (on ENST00000380664; = p.P1344= on NM_183387.3) | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- HBEGF | c.276G>A p.G92= | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- LAMB2 | c.909G>A p.E303= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs372432021; called by muse, mutect2, varscan2
- NUP205 | c.4929G>A p.G1643= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- NUP210 | c.4845C>T p.F1615= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- ST13 | c.687G>A p.Q229= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1393544018; called by muse, mutect2, varscan2
- SYNE2 | c.1035C>T p.S345= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- ZDHHC11 | c.30C>T p.S10= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs770290246; called by muse, mutect2, varscan2
- DNAH14 | c.9206-2413T>G | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-784C>T | Intron (SNP) | VAF 11/140 reads (8%) | catalogued as rs752280814; called by muse, mutect2
